Gene-level copy-number profile of tumor specimen C3L-00965-03 from CPTAC case C3L-00965, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 63.8 years (23,305 days).
Specimen C3L-00965-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c6b98046-f0cc-456e-973f-5f8dffb279b6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00965-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/7f71bb77-17b5-41c2-85ca-1ecaf484f39b

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 50; copy number 1: 27,960; copy number 2: 24,352; copy number 3: 6,288; copy number 4: 133; copy number 5: 48; copy number 6: 38; copy number 7: 3; copy number 10: 25; copy number 16: 5.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:241,893,988–241,902,551, 1 gene (within-gene range 0–2): FAM240C.
- chr15:32,175,247–32,186,475, 2 genes: Y_RNA, AC068448.1.
- chr16:55,760,566–55,793,960, 1 gene: CES1P1.
- chr21:7,744,962–8,454,792, 26 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1.
- chr21:9,068,361–9,129,752, 3 genes (within-gene range 0–1): TEKT4P2, SOWAHCP2, CR392039.2.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 6,539 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,923,317–151,831,845, 104 genes, copy number 3 (broad region; genes not listed).
- chr1:160,062,461–162,370,475, 105 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr1:182,407,621–184,672,166, 46 genes, copy number 3: LINC00272, RGSL1, AL139344.1, TEDDM2P, RNASEL, Metazoa_SRP, RGS16, LINC01686, RGS8, LINC01688, AL353778.1, NPL, AL355999.1, DHX9, SHCBP1L, HMGN1P4, 5S_rRNA, AL450304.1, KRT18P28, RNU6-41P, LAMC1, LAMC1-AS1, LAMC2, NMNAT2, AL354953.1, RPS3AP8, AL449223.1, SMG7-AS1, SMG7, NCF2, ARPC5, RGL1, APOBEC4, AL157899.1, AL590422.1, COLGALT2, TSEN15, Y_RNA, Y_RNA, AL445228.1, RN7SL654P, AL445228.2, C1orf21, AL078645.1, AL078645.2, AL713852.1.
- chr1:200,253,419–203,904,013, 120 genes, copy number 3 (broad region; genes not listed).
- chr1:205,134,646–206,126,805, 36 genes, copy number 3: AC093422.2, DSTYK, AC093422.1, TMCC2, TMCC2-AS1, NUAK2, KLHDC8A, SNRPGP10, LEMD1-AS1, LEMD1, BLACAT1, MIR135B, LEMD1-DT, CDK18, RNU2-19P, MFSD4A, RNU6-418P, ELK4, AC096533.1, SLC45A3, Metazoa_SRP, NUCKS1, SNORA72, RAB29, SLC41A1, AC119673.2, PM20D1, SLC26A9, AL713965.1, RAB7B, CTSE, BX571818.1, RHEX, AC244035.3, AVPR1B, AC244035.1.
- chr3:93,843,764–198,123,232, 1,753 genes, copy number 3–4 (broad region; genes not listed).
- chr8:64,091–43,674,591, 910 genes, copy number 3 (broad region; genes not listed).
- chr8:97,241,742–145,066,685, 742 genes, copy number 3 (broad region; genes not listed).
- chr12:12,310–563,509, 17 genes, copy number 4: DDX11L8, WASH8P, FAM138D, IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3.
- chr12:990,509–4,405,490, 78 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr12:6,451,690–6,784,161, 32 genes, copy number 4 (within-gene range 2–4): TAPBPL, VAMP1, AC005840.4, AC005840.3, MRPL51, NCAPD2, SCARNA10, AC006064.5, AC006064.3, GAPDH, AC006064.4, IFFO1, AC006064.1, NOP2, AC006064.6, CHD4, AC006064.2, SCARNA11, LPAR5, ACRBP, ING4, AC125494.1, ZNF384, PIANP, RNU6-781P, AC125494.3, COPS7A, AC125494.2, MLF2, PTMS, LAG3, RN7SL380P.
- chr12:25,385,670–27,972,733, 65 genes, copy number 4 (broad region; genes not listed).
- chr14:18,333,726–19,976,659, 84 genes, copy number 3 (broad region; genes not listed).
- chr17:26,981,694–83,240,804, 2,108 genes, copy number 3 (broad region; genes not listed).
- chr19:28,294,093–31,595,720, 58 genes, copy number 5–6: AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1, AC008794.1, LINC02841, AC011525.1, AC011525.2.
- chr20:30,214,765–34,825,651, 146 genes, copy number 3–16 (broad region; genes not listed).
- chr20:61,953,469–62,065,810, 1 gene, copy number 3 (within-gene range 2–3): TAF4.
- chr20:62,037,429–64,327,972, 134 genes, copy number 3 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 25,123. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
